Somatic mutation profile of tumor specimen TCGA-AB-2802-03B (aliquot TCGA-AB-2802-03B-01W-0728-08) from TCGA case TCGA-AB-2802, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.3 years (18,385 days).
Specimen TCGA-AB-2802-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7926e6d1-6ee6-4c1c-8367-f70e676c3e15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2802-11B (Solid Tissue Normal), aliquot TCGA-AB-2802-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57915934-129a-4428-9003-6d23710b26d9

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 36/83 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs377577594, COSV53036332, COSV53037241, COSV53063308; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 25/67 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTPN11 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 52/116 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs397507510, CD055729, CM021127, CM101143, COSV61004841, COSV61006072, COSV61006164; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKRD30A | c.2114C>T p.A705V (on ENST00000611781; = p.A649V on NM_052997.2) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs767521584, COSV64607238; called by muse, mutect2, varscan2
- BMPR1A | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1554890768, COSV100923208; ClinVar: uncertain significance; called by muse, mutect2
- RAB5IF | c.403C>T p.H135Y (on ENST00000373852 / NM_001199534.2; = p.A125= on NM_018840.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV53410736; called by muse, mutect2, varscan2
- TBX15 | c.493A>T p.I165F (on ENST00000369429 / NM_001330677.2; = p.I59F on NM_152380.3) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52869293; called by mutect2, varscan2
- TCHHL1 | c.2636A>G p.Q879R | Missense Mutation (SNP) | VAF 88/215 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.941); catalogued as COSV64285267; called by muse, mutect2, varscan2
- EP400 | c.1791G>A p.Q597= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as COSV57768133; called by muse, mutect2, varscan2
- F13A1 | c.780C>T p.S260= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV99344226; called by muse, mutect2
- KRT74 | c.913C>T p.L305= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs762908755, COSV59770858; called by muse, mutect2, varscan2
